Gene-level copy-number profile of tumor specimen TCGA-NP-A5H5-01A from TCGA case TCGA-NP-A5H5, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 79.5 years (29,034 days).
Specimen TCGA-NP-A5H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8d8bed8-5779-409e-88e7-7b163f2920b9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-NP-A5H5-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/449cc050-640a-48ae-83b0-3e0e50ea5a87

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 26; copy number 2: 145; copy number 3: 32,442; copy number 4: 61; copy number 5: 51; copy number 6: 25,555; copy number 7: 55.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–3): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–3): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr8:7,190,901–7,191,563, 1 gene: RPS3AP33.
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–2): AC105233.4.
- chr8:8,154,308–8,244,865, 5 genes: ENPP7P1, FAM85B, AC068020.1, FAM86B3P, ALG1L13P.
- chr9:41,979,352–42,354,454, 7 genes: CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr21:7,744,962–8,680,934, 28 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.
- chr21:9,053,122–9,129,752, 4 genes: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 55 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:56,805,336–57,074,664, 9 genes, copy number 7: CICP28, AC118758.2, AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1.
- chr15:20,228,620–21,167,357, 46 genes, copy number 7: RHPN2P1, CHEK2P2, AC026495.1, HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P, AC023310.2, IGHV1OR15-6, AC023310.4, NBEAP1, AC131280.1, AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
